Somatic mutation profile of tumor specimen TCGA-AD-6964-01A (aliquot TCGA-AD-6964-01A-11D-1924-10) from TCGA case TCGA-AD-6964, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 58.7 years (21,457 days).
Specimen TCGA-AD-6964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 321b82ae-1e2c-4573-b552-9a99d7024931.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6964-10A (Blood Derived Normal), aliquot TCGA-AD-6964-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e8f8dea-3126-4c11-a5c8-15885f6a9d5c

The open-access MAF lists 1,922 somatic variants for this specimen: 1,357 protein-altering or splice-affecting, 397 silent, 168 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,029, Silent 397, Frame Shift Del 179, 3'UTR 76, Frame Shift Ins 65, Intron 50, Nonsense Mutation 39, Splice Site 21, RNA 19, Splice Region 15, 5'UTR 12, In Frame Del 9.

Variants (750 of 1,922; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD8 | c.5607dup p.D1870Rfs*3 (on ENST00000646647 / NM_001170629.2; = p.D1591Rfs*3 on NM_020920.4) | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | catalogued as rs774152851; ClinVar: pathogenic; called by mutect2, pindel
- COL1A1 | c.2424del p.G809Afs*299 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs1114167391, CD123308; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 32/119 reads (27%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- DCX | c.681del p.K227Nfs*10 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs587783579, CM087665, COSV100576527; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- OAT | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as rs121965054, CM920528, COSV64347752; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 27/272 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PKD1 | c.9898G>A p.G3300R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs777024498, CM1314592; ClinVar: likely benign / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3801del p.C1268Afs*4 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs587784374; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TCIRG1 | c.480dup p.P161Afs*66 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as rs1554995341; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AACS | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.253); catalogued as rs1475418232, COSV55537515; called by muse, mutect2, varscan2
- AARS2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as rs1420621627, COSV55115120; called by muse, mutect2, varscan2
- ABCA12 | c.3547T>C p.Y1183H (on ENST00000272895 / NM_173076.3; = p.Y865H on NM_015657.3) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55961616; called by muse, mutect2, varscan2
- ABCA3 | c.5096C>T p.T1699I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV57054528; called by muse, mutect2, varscan2
- ABCC8 | c.681A>T p.K227N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV56851532; called by muse, mutect2
- ABHD16A | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65451871; called by muse, mutect2, varscan2
- AC004922.1 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as rs547379680, COSV53557378; called by muse, mutect2, varscan2
- AC005833.1 | c.1172A>T p.D391V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0); catalogued as COSV52897913; called by muse, mutect2, varscan2
- AC013489.1 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51551629; called by muse, mutect2, varscan2
- ACAD11 | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as COSV53896914; called by muse, mutect2, varscan2
- ACAP3 | c.547_549del p.K183del | In Frame Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs1468346830; called by pindel, varscan2
- ACLY | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV61250967; called by muse, mutect2, varscan2
- ACO2 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV53443165; called by muse, mutect2, varscan2
- ACOT1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58573297; called by muse, varscan2
- ACP6 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV65077131, COSV65078054; called by muse, mutect2, varscan2
- ACP7 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100488646; called by muse, mutect2, varscan2
- ACSL6 | c.1625G>A p.G542E (on ENST00000379240; = p.G567E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57299413; called by muse, mutect2, varscan2
- ACSL6 | c.1310C>T p.P437L (on ENST00000379240; = p.P462L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57299445; called by muse, mutect2, varscan2
- ACTA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.161); catalogued as COSV64203495; called by muse, mutect2, varscan2
- ACTN2 | c.2668G>A p.G890R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536297856, COSV100856853, COSV63976618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1B | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV56703533; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE2 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs774168050, COSV100215918, COSV59693209, COSV59696547; called by muse, mutect2, varscan2
- ADGRF4 | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs897059555, COSV51952992, COSV51954008; called by muse, mutect2, varscan2
- ADGRG4 | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs749780022, COSV99794328; called by mutect2, varscan2
- ADGRL3 | c.2483C>T p.A828V (on ENST00000506720 / NM_001322402.2; = p.A760V on NM_015236.6) | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV72229455, COSV72230768; called by muse, mutect2, varscan2
- ADGRL3 | c.4588C>T p.P1530S (on ENST00000506720 / NM_001322402.2; = p.P1419S on NM_015236.6) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV72230769; called by muse, mutect2, varscan2
- ADIPOR1 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1414059227, COSV61851651; called by muse, mutect2, varscan2
- AFF2 | c.3490T>C p.S1164P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53992205; called by muse, mutect2, varscan2
- AGBL4 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV65742076; called by mutect2, varscan2
- AGPAT3 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52370765; called by muse, mutect2, varscan2
- AGPAT4 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV57249031; called by muse, mutect2, varscan2
- AGTPBP1 | c.2642C>T p.T881I (on ENST00000357081 / NM_001330701.2; = p.T841I on NM_015239.2) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61272415; called by muse, mutect2, varscan2
- AHDC1 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as COSV55939422; called by muse, mutect2, varscan2
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 39/161 reads (24%) | catalogued as rs752653022, COSV63698332; called by mutect2, varscan2
- AK9 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs1315434899, COSV53421526; called by muse, mutect2, varscan2
- AKAP12 | c.3479del p.P1160Lfs*18 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as COSV53580835; called by mutect2, pindel, varscan2
- AKAP9 | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs752626437, COSV62348117; ClinVar: uncertain significance; called by muse, mutect2
- AKAP9 | c.4839G>A p.M1613I | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62348132; called by muse, varscan2
- ALDH4A1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs142969512, COSV51893094; called by muse, mutect2, varscan2
- ANGPT1 | c.1338A>G p.G446= | Splice Region (SNP) | VAF 12/118 reads (10%) | catalogued as rs749929743; called by mutect2, varscan2
- ANK1 | c.3434T>C p.I1145T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs767714240, COSV55883385; called by mutect2, varscan2
- ANK2 | c.8176A>G p.T2726A | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs781344591; called by muse, mutect2, varscan2
- ANKMY1 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1469287729, COSV56035216; called by muse, mutect2, varscan2
- ANKRD45 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60961350; called by muse, mutect2, varscan2
- ANKRD45 | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 79/328 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60961359; called by muse, mutect2, varscan2
- ANKS3 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58509323; called by muse, mutect2, varscan2
- ANO1 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV104412512; called by muse, varscan2
- ANO2 | c.1373T>C p.L458P (on ENST00000356134 / NM_001278597.3; = p.L462P on NM_001278596.3) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1407453667, COSV59026054; called by muse, mutect2, varscan2
- AP002748.5 | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59149290; called by muse, mutect2, varscan2
- AP3B2 | c.3124G>T p.G1042W (on ENST00000261722; = p.G1036W on NM_004644.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55610185; called by muse, mutect2, varscan2
- APBB2 | c.2258C>T p.P753L (on ENST00000295974 / NM_001166050.2; = p.P754L on NM_004307.2) | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.851); catalogued as rs1460566186, COSV55953763; called by muse, mutect2, varscan2
- APCDD1L | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV64486588; called by muse, mutect2, varscan2
- APEX1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); catalogued as rs778698391, COSV51658052; called by muse, mutect2, varscan2
- ARAP1 | c.2549T>C p.V850A (on ENST00000393609 / NM_001040118.2; = p.V605A on NM_015242.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1471676337; called by muse, mutect2, varscan2
- ARAP2 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | catalogued as COSV58287531; called by muse, mutect2, varscan2
- ARHGAP11A | c.297+1G>A p.X99_splice | Splice Site (SNP) | VAF 27/120 reads (23%) | catalogued as COSV64381090; called by muse, mutect2, varscan2
- ARHGAP29 | c.2335A>T p.T779S | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53112645; called by muse, varscan2
- ARHGAP42 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53978648; called by muse, mutect2
- ARID1B | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1369594791, COSV51662864; called by muse, mutect2, varscan2
- ARID2 | c.652del p.S218Pfs*74 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | catalogued as rs1433103583; called by mutect2, pindel, varscan2
- ARL8B | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs780847749; called by muse, mutect2, varscan2
- ART5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs762141846, COSV63364256; called by muse, mutect2, varscan2
- ARVCF | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745796776, COSV54266773; called by mutect2, varscan2
- ASH2L | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV51699935; called by muse, mutect2, varscan2
- ASIC4 | c.1393del p.L465Cfs*16 (on ENST00000347842 / NM_182847.3; = p.L484Cfs*16 on NM_018674.6) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV61731905; called by mutect2, pindel, varscan2
- ASPH | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as COSV62859500; called by muse, mutect2, varscan2
- ASXL1 | c.2535dup p.S846Qfs*5 | Frame Shift Ins (INS) | VAF 31/127 reads (24%) | catalogued as rs750170870; called by mutect2, pindel, varscan2
- ASXL2 | c.3007A>G p.T1003A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1291050011; called by mutect2, varscan2
- ATF6B | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64351401, COSV64351974; called by muse, mutect2, varscan2
- ATF7IP | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53771946; called by muse, mutect2, varscan2
- ATG2A | c.1171T>A p.S391T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as COSV65967077; called by muse, mutect2, varscan2
- ATP13A1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as rs1229389137; called by muse, mutect2, varscan2
- ATP1A2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779985796, COSV63402581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV59498012; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs1288664341; called by mutect2, pindel
- AUTS2 | c.453T>A p.D151E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV61406487; called by muse, mutect2, varscan2
- AUTS2 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs139511589; called by muse, mutect2, varscan2
- AVPR1B | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65638189; called by muse, mutect2, varscan2
- B3GALT1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs756735753, COSV59908835; called by muse, mutect2, varscan2
- B4GALNT4 | c.2620C>A p.L874M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57323689; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.141); catalogued as COSV50056512; called by muse, mutect2, varscan2
- BCL3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.267); catalogued as COSV51234304; called by muse, mutect2, varscan2
- BCL9 | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV52340267; called by muse, mutect2, varscan2
- BCL9 | c.2726dup p.V910Cfs*42 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | catalogued as rs1553205212; called by mutect2, varscan2
- BCL9L | c.3665C>T p.S1222F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52689573; called by muse, mutect2, varscan2
- BCL9L | c.1448del p.P483Rfs*19 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | catalogued as rs752970264; called by mutect2, pindel, varscan2
- BDH1 | c.469A>G p.S157G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV64018694; called by muse, mutect2, varscan2
- BEGAIN | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.836); catalogued as COSV62068963; called by muse, mutect2, varscan2
- BEX5 | c.11T>A p.V4D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV61329115; called by muse, varscan2
- BICC1 | c.1831A>G p.T611A | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54064145, COSV99570836; called by muse, mutect2, varscan2
- BID | c.81-1G>T p.X27_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | catalogued as rs1199829016, COSV58007941; called by muse, mutect2, varscan2
- BMPR1A | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64406378; called by muse, mutect2
- BRCA2 | c.5881A>G p.S1961G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV66454901; called by muse, mutect2, varscan2
- BTBD8 | c.3799G>T p.E1267* (on ENST00000636805 / NM_001376131.1; = p.E754* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV64884612; called by muse, mutect2, varscan2
- BTN1A1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV55067998; called by muse, mutect2, varscan2
- C11orf94 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs568211499; called by muse, mutect2, varscan2
- C1orf100 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs144063808; called by muse, mutect2, varscan2
- C1orf21 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs1281806323; called by muse, mutect2
- C1orf87 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs762859456, COSV64597005; called by muse, mutect2, varscan2
- C22orf23 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569156289; called by muse, varscan2
- C2CD5 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61724961; called by muse, mutect2, varscan2
- C3orf20 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs533425035, COSV53785911; called by muse, mutect2, varscan2
- C4BPA | c.1598C>A p.P533Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65536556; called by muse, mutect2, varscan2
- CACNA1E | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV62398786; called by muse, mutect2, varscan2
- CACNA1G | c.1546del p.R516Gfs*48 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs1401299999; called by mutect2, varscan2
- CACNA1G | c.3620G>A p.R1207H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs545668335, COSV61729387; called by mutect2, varscan2
- CACNA1H | c.5173+1G>A p.X1725_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100670826; called by muse, mutect2
- CACNA1H | c.6965G>A p.R2322Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1468102052, COSV52352905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.977T>A p.L326H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62940310; called by muse, mutect2, varscan2
- CACNB4 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52395067; called by muse, mutect2
- CADPS2 | c.525A>C p.E175D | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57366163; called by muse, mutect2, varscan2
- CALD1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV62648529; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPNS2 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV50896148; called by muse, mutect2, varscan2
- CARD11 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV67798697; called by muse, mutect2, varscan2
- CARHSP1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs368130205; called by muse, mutect2, varscan2
- CARMIL2 | c.1153A>G p.R385G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.264); catalogued as COSV58027165; called by muse, mutect2, varscan2
- CARMIL2 | c.2676+1G>A p.X892_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV58027181; called by muse, mutect2, varscan2
- CASP7 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61882001; called by muse, mutect2, varscan2
- CASZ1 | c.4402T>C p.F1468L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65458284; called by muse, mutect2, varscan2
- CCDC14 | c.1762C>T p.R588C (on ENST00000488653; = p.R540C on NM_022757.5) | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754428441, COSV59945191; called by muse, mutect2, varscan2
- CCDC40 | c.2518C>A p.L840M | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as COSV66475426; called by muse, mutect2, varscan2
- CCDC66 | c.734A>T p.D245V (on ENST00000394672 / NM_001353147.1; = p.D211V on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58304810; called by muse, mutect2, varscan2
- CCDC88A | c.4103G>A p.R1368H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966116188, COSV55069138; called by muse, mutect2, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCM2L | c.1656C>G p.D552E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1170023018, COSV52950570; called by muse, mutect2, varscan2
- CD163L1 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.607); catalogued as COSV58017424; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC40 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.445); catalogued as COSV57009981; called by muse, mutect2, varscan2
- CDCA8 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59239005; called by muse, mutect2, varscan2
- CDH1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs550612843, COSV55733838; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- CDH23 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54933439, COSV54937014; called by muse, mutect2, varscan2
- CDH6 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54071108; called by muse, mutect2, varscan2
- CDHR3 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.426); catalogued as COSV58417800; called by muse, mutect2, varscan2
- CDR1 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV65164344; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CELSR1 | c.7462G>A p.V2488I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as rs199555924; called by muse, mutect2, varscan2
- CELSR3 | c.9532C>T p.R3178W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs758292109, COSV50873748; called by muse, mutect2, varscan2
- CELSR3 | c.7018del p.A2340Pfs*45 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV50904380; called by mutect2, pindel
- CELSR3 | c.4069T>C p.Y1357H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50874062; called by muse, mutect2, varscan2
- CEMIP | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as COSV54988983; called by muse, mutect2, varscan2
- CEMIP2 | c.3533C>T p.P1178L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs753231373, COSV65487578; called by muse, mutect2, varscan2
- CEMIP2 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV65487585; called by muse, mutect2, varscan2
- CENPU | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV55657942; called by muse, mutect2
- CEP162 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs148340487; called by muse, mutect2, varscan2
- CEP295NL | c.1526T>C p.M509T | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV53161896; called by muse, mutect2, varscan2
- CEP295NL | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs549779113; called by mutect2, varscan2
- CES3 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.198); catalogued as rs138443573; called by muse, varscan2
- CFAP251 | c.3379A>G p.T1127A | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV56611093; called by muse, mutect2, varscan2
- CFAP43 | c.2864A>G p.H955R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.262); catalogued as rs1320021671; called by muse, mutect2, varscan2
- CFAP43 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV53378321; called by muse, mutect2, varscan2
- CFAP61 | c.1427G>A p.G476D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs200764112; called by muse, mutect2, varscan2
- CFH | c.3554C>G p.A1185G | Missense Mutation (SNP) | VAF 20/578 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV66414904; called by muse, mutect2
- CHD5 | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52416051; called by muse, varscan2
- CHEK1 | c.700dup p.I234Nfs*11 | Frame Shift Ins (INS) | VAF 22/98 reads (22%) | catalogued as rs1565368022; called by mutect2, varscan2
- CHL1 | c.1732A>G p.I578V (on ENST00000397491 / NM_001253387.1; = p.I594V on NM_006614.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1206325980; called by muse, mutect2, varscan2
- CHRNA3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775325162, COSV100468651, COSV58775586; called by muse, mutect2, varscan2
- CHRNA4 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV64719692; called by muse, mutect2, varscan2
- CHRND | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51320388; called by muse, mutect2, varscan2
- CHST3 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs866792272, COSV64151134; called by muse, mutect2, varscan2
- CHST8 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV52859483, COSV52860101; called by muse, mutect2, varscan2
- CIC | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV50583454; called by muse, mutect2
- CLCN1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58370496; called by muse, mutect2, varscan2
- CLCN4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs184474252, COSV66466815; called by muse, mutect2, varscan2
- CLDN20 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs778274068; called by muse, mutect2, varscan2
- CLIP4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 39/181 reads (22%) | catalogued as COSV60749538; called by muse, mutect2, varscan2
- CLK2 | c.1217G>A p.R406Q (on ENST00000368361 / NM_001294339.2; = p.R405Q on NM_003993.4) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.088); catalogued as rs534718482, COSV56945494; called by muse, mutect2, varscan2
- CLOCK | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV59402281; called by muse, mutect2, varscan2
- CLPX | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV55644794; called by muse, mutect2, varscan2
- CLSPN | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52051923; called by muse, mutect2
- CLUH | c.3241G>A p.A1081T (on ENST00000435359; = p.A1120T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as rs372755886; called by mutect2, varscan2
- CMTM3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as rs778469660, COSV62680139; called by muse, mutect2, varscan2
- CNGB3 | c.2393T>A p.V798D | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60690866; called by muse, mutect2, varscan2
- CNTF | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV60157993; called by muse, mutect2
- CNTN1 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767086250, COSV61640492; ClinVar: uncertain significance; called by mutect2, varscan2
- CNTN5 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54316859; called by muse, mutect2, varscan2
- CNTN6 | c.1068A>T p.E356D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); catalogued as COSV63174501, COSV63178303; called by muse, mutect2
- CNTNAP1 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1481806507, COSV52849055; called by muse, mutect2, varscan2
- CNTNAP5 | c.2189A>T p.D730V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70489140; called by muse, mutect2, varscan2
- COL18A1 | c.4540G>A p.D1514N (on ENST00000359759 / NM_130444.3; = p.D1279N on NM_030582.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as rs775390699, COSV60586163, COSV60589394; called by muse, mutect2, varscan2
- COL19A1 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59574990, COSV59575041; called by muse, mutect2, varscan2
- COL19A1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 52/164 reads (32%) | catalogued as rs759890824, COSV59574999; called by muse, mutect2, varscan2
- COL23A1 | c.730-2A>G p.X244_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | catalogued as COSV101178098; called by muse, mutect2, varscan2
- COL26A1 | c.820G>A p.A274T (on ENST00000313669 / NM_001278563.3; = p.A272T on NM_133457.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as rs748332700, COSV100561816; called by mutect2, varscan2
- COLEC11 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778329349, COSV52594204; called by muse, mutect2, varscan2
- COPS5 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99138024; called by muse, mutect2
- COQ5 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs755564043, COSV56019232; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 23/110 reads (21%) | catalogued as rs777945397; called by mutect2, varscan2
- CR1 | c.4595G>A p.S1532N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV65458768; called by muse, mutect2, varscan2
- CRTC1 | c.1277dup p.E427Rfs*24 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs760791352; called by mutect2, varscan2
- CSGALNACT2 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs746251791, COSV65675460; called by muse, mutect2, varscan2
- CSMD2 | c.1300A>T p.I434F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV53918654; called by muse, mutect2
- CSTF1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53858988; called by muse, mutect2, varscan2
- CT83 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as COSV64141094; called by muse, mutect2, varscan2
- CTAGE1 | c.1103G>T p.R368M | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66943674; called by muse, mutect2, varscan2
- CTAGE4 | c.2168del p.P723Hfs*30 | Frame Shift Del (DEL) | VAF 17/158 reads (11%) | catalogued as rs1237225733; called by mutect2, pindel, varscan2
- CTAGE9 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100020235; called by muse, mutect2, varscan2
- CTBP2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.357); catalogued as rs1395207217, COSV58334686; called by muse, mutect2, varscan2
- CTTNBP2 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV50407240, COSV99353608; called by muse, mutect2, varscan2
- CTTNBP2NL | c.333G>A p.V111= | Splice Region (SNP) | VAF 19/87 reads (22%) | catalogued as rs780407855, COSV54744875; called by muse, mutect2, varscan2
- CUL3 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV52365460; called by muse, mutect2, varscan2
- CUX2 | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55631844; called by muse, mutect2, varscan2
- CYB5D1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs977352006, COSV54682325; called by muse, varscan2
- CYP20A1 | c.903dup p.L302Ifs*3 | Frame Shift Ins (INS) | VAF 42/210 reads (20%) | catalogued as rs778884333; called by mutect2, varscan2
- CYP4F12 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV61174152; called by muse, mutect2, varscan2
- CYSTM1 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV55835759; called by muse, mutect2, varscan2
- CYTIP | c.914T>G p.I305S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV51634092; called by muse, mutect2, varscan2
- DBX2 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 51/241 reads (21%) | catalogued as rs754618578, COSV60337740; called by muse, mutect2, varscan2
- DCAF4L1 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV60787482; called by muse, mutect2, varscan2
- DCAF4L2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV60478217, COSV60481290; called by mutect2, varscan2
- DCTN1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs748949872, COSV62620419; called by muse, mutect2, varscan2
- DDB1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57103250; called by muse, mutect2, varscan2
- DDX25 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.931); catalogued as COSV54990901; called by muse, mutect2, varscan2
- DDX3X | c.1537A>G p.I513V (on ENST00000399959; = p.I514V on NM_001356.5) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.102); catalogued as COSV67863763; called by muse, mutect2, varscan2
- DDX60 | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs551895137, COSV67097033; called by muse, mutect2, varscan2
- DDX60L | c.2540T>C p.F847S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV52714533; called by muse, mutect2, varscan2
- DENND3 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.426); catalogued as rs1202855347, COSV52802053; called by muse, mutect2, varscan2
- DGAT1 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60048255; called by muse, mutect2, varscan2
- DHRSX | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58134589; called by muse, mutect2, varscan2
- DHX36 | c.599T>C p.M200T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57673489; called by muse, mutect2, varscan2
- DHX38 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV51698439; called by muse, mutect2, varscan2
- DHX57 | c.3659C>T p.A1220V | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746909137; called by muse, mutect2
- DIAPH1 | c.3425G>A p.R1142Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs200419320, COSV53883327; called by muse, mutect2, varscan2
- DLG1 | c.2530C>T p.R844C (on ENST00000419354 / NM_001290983.1; = p.R866C on NM_004087.2) | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751084251, COSV58383922; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs762874947; called by mutect2, varscan2
- DMBT1 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 23/440 reads (5%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.699); catalogued as COSV57546032; called by muse, mutect2
- DMBT1 | c.7192G>A p.V2398M (on ENST00000338354 / NM_001377530.1; = p.V1641M on NM_004406.3) | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1324587780, COSV57546038; called by muse, mutect2, varscan2
- DNAH1 | c.11891C>T p.A3964V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV56235135; called by muse, mutect2, varscan2
- DNAH17 | c.13043A>G p.D4348G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145746; called by muse, mutect2, varscan2
- DNAH2 | c.3784A>G p.T1262A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs781018026; called by muse, mutect2, varscan2
- DNAH3 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1013012929, COSV54511759, COSV99770890; called by muse, mutect2, varscan2
- DNAH7 | c.6927dup p.P2310Tfs*50 | Frame Shift Ins (INS) | VAF 25/207 reads (12%) | catalogued as rs747230864; called by mutect2, pindel, varscan2
- DNAH8 | c.12178G>A p.V4060M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1040033714, COSV59451626; called by muse, mutect2
- DNAJB2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs11559157, COSV60676835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB5 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56625847; called by muse, mutect2, varscan2
- DNAJC27 | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV53095310; called by muse, mutect2, varscan2
- DNLZ | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52517668; called by muse, mutect2, varscan2
- DOCK11 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755708340, COSV52240247; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK4 | c.5863C>T p.R1955W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs781555979, COSV70237692; called by muse, mutect2, varscan2
- DOCK5 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs139728505; called by muse, mutect2, varscan2
- DOCK5 | c.4966T>A p.S1656T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99376036; called by muse, mutect2
- DRC3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201211532, COSV58263746; called by muse, mutect2, varscan2
- DROSHA | c.3509A>G p.H1170R | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV60777066; called by muse, mutect2, varscan2
- DSCAM | c.4564A>G p.T1522A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV101259109; called by muse, mutect2
- DST | c.20645C>T p.A6882V (on ENST00000361203 / NM_001374722.1; = p.A4579V on NM_015548.5) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV55018553; called by muse, mutect2
- DTNB | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56474923, COSV56477986; called by muse, mutect2, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs1381179969; called by mutect2, pindel, varscan2
- DUSP4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375453930; called by muse, mutect2, varscan2
- DVL1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1047862834, COSV59563724; called by muse, mutect2, varscan2
- DYRK4 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs760827391, COSV50540058; called by muse, mutect2, varscan2
- DZIP1 | c.2188G>A p.E730K (on ENST00000347108; = p.E711K on NM_014934.5) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.263); catalogued as rs1335851214, COSV61266265; called by muse, mutect2, varscan2
- EAF2 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56544612; called by muse, mutect2, varscan2
- EBF3 | c.1148C>T p.A383V (on ENST00000355311 / NM_001375392.1; = p.A374V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs546805685, COSV62471735; called by mutect2, varscan2
- EFTUD2 | c.2127G>A p.W709* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53655746; called by muse, mutect2, varscan2
- EFTUD2 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as COSV68182087; called by muse, mutect2, varscan2
- EGF | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54479751; called by muse, mutect2, varscan2
- EGFR | c.3094A>T p.T1032S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.297); catalogued as COSV51806191; called by mutect2, varscan2
- EGFR | c.3289G>A p.V1097I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775345513, COSV51773844; called by muse, varscan2
- EHD3 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs370790409; called by muse, mutect2, varscan2
- EHD4 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55005181; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF2AK1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as rs765245380, COSV52240145; called by muse, mutect2, varscan2
- EIF3I | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs759750490, COSV61889826; called by muse, mutect2, varscan2
- EIF3M | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV60072915; called by muse, mutect2, varscan2
- EIF5A | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as COSV59750196; called by muse, mutect2, varscan2
- ELF5 | c.669A>T p.R223S (on ENST00000312319 / NM_198381.2; = p.R213S on NM_001422.4) | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV56629061; called by muse, varscan2
- ELP6 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1310548148, COSV56132355; called by muse, mutect2, varscan2
- ENAH | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV52868610; called by muse, mutect2, varscan2
- ENGASE | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.253); catalogued as COSV56135966; called by muse, mutect2, varscan2
- ENKD1 | c.640del p.R214Gfs*14 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs772512087; called by mutect2, pindel, varscan2
- ENOX2 | c.710G>A p.R237H (on ENST00000338144 / NM_001382520.1; = p.R208H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs779235219, COSV57652489; called by muse, mutect2, varscan2
- ENPEP | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV54452062; called by muse, mutect2, varscan2
- ENTPD4 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375242682; called by mutect2, varscan2
- EPHA10 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV57621565, COSV57624463; called by muse, mutect2, varscan2
- EPHA7 | c.2932A>T p.M978L | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65183981; called by muse, mutect2, varscan2
- EPHB2 | c.2635A>G p.T879A (on ENST00000400191 / NM_001309193.2; = p.T880A on NM_004442.7) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.137); catalogued as rs767807199, COSV65862999; called by muse, mutect2, varscan2
- EPHB6 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.329); catalogued as COSV63892030; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 16/116 reads (14%) | catalogued as rs765115164; called by mutect2, varscan2
- ETNK2 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1218035175, COSV65817861; called by muse, mutect2, varscan2
- EXD2 | c.1651A>T p.I551F (on ENST00000312994 / NM_001193362.1; = p.I426F on NM_018199.3) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV57279829; called by muse, mutect2, varscan2
- EXD3 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs185546260; called by mutect2, varscan2
- EXOSC1 | c.32-1G>T p.X11_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV61749206; called by muse, mutect2, varscan2
- EXTL1 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65337681; called by muse, mutect2, varscan2
- EXTL3 | c.1548G>A p.W516* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV55038314; called by muse, mutect2, varscan2
- EYS | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV60987728; called by muse, mutect2, varscan2
- EZH2 | c.1085G>A p.S362N (on ENST00000460911 / NM_001203247.2; = p.S367N on NM_004456.5) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57454525; called by muse, mutect2, varscan2
- F8 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); catalogued as COSV64274311; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM153B | c.751C>T p.P251S (on ENST00000253490; = p.P174S on NM_001265615.1) | Missense Mutation (SNP) | VAF 87/600 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.803); catalogued as rs771479337, COSV53686746; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM193A | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs780064243, COSV61194758; called by mutect2, varscan2
- FAM207A | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV52420690; called by muse, mutect2, varscan2
- FAM76B | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.05); catalogued as COSV62556565; called by muse, mutect2, varscan2
- FAM83E | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV50031827; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FAN1 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); catalogued as COSV62950827; called by muse, mutect2, varscan2
- FANCA | c.3828+7C>T | Splice Region (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99234555; called by muse, mutect2
- FANCD2 | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55039296; called by muse, mutect2, varscan2
- FARP1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.191); catalogued as COSV60339013; called by muse, mutect2, varscan2
- FARP2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs371446032; called by muse, mutect2, varscan2
- FAT4 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67888432; called by muse, mutect2, varscan2
- FAU | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV54195145; called by muse, mutect2, varscan2
- FBL | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as rs868256983, COSV55682813; called by muse, mutect2, varscan2
- FBN1 | c.7968G>T p.Q2656H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV57318810; called by muse, mutect2, varscan2
- FBN1 | c.4108G>T p.G1370* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV57318814; called by muse, mutect2, varscan2
- FBXL18 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.127); catalogued as rs766801813; called by muse, mutect2
- FBXO10 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52833349; called by muse, mutect2
- FBXO38 | c.1877A>T p.E626V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV57028268; called by muse, mutect2, varscan2
- FCRL2 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs756107904, COSV63833780; called by muse, mutect2
- FDFT1 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV55042603; called by muse, mutect2, varscan2
- FGF13 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.144); catalogued as COSV59546320; called by muse, mutect2, varscan2
- FGFR3 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.167); catalogued as COSV53403315; called by muse, mutect2, varscan2
- FHDC1 | c.71T>C p.F24S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV52600396; called by muse, mutect2, varscan2
- FHOD1 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50761445; called by muse, mutect2, varscan2
- FLCN | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV53259822; called by muse, mutect2, varscan2
- FLII | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs773795422, COSV58945373; called by muse, mutect2, varscan2
- FLNA | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61044313; called by muse, mutect2, varscan2
- FLRT1 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs771847776, COSV55361380; called by muse, mutect2, varscan2
- FLT4 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV56109413, COSV56110703; called by muse, mutect2, varscan2
- FLYWCH1 | c.873G>T p.K291N (on ENST00000253928 / NM_001308068.2; = p.K290N on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54146519; called by muse, mutect2, varscan2
- FLYWCH1 | c.1240G>A p.A414T (on ENST00000253928 / NM_001308068.2; = p.A413T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs529892902, COSV54146544; called by muse, mutect2, varscan2
- FMN2 | c.1401G>C p.K467N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV60449174, COSV60449937; called by muse, mutect2, varscan2
- FN3KRP | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.532); catalogued as rs756638100, COSV53929834; called by muse, mutect2, varscan2
- FOLH1 | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57046346; called by muse, mutect2, varscan2
- FOXI3 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as COSV101230917, COSV67916689; called by muse, mutect2, varscan2
- FOXM1 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145831539; called by muse, mutect2, varscan2
- FPR2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60673087; called by muse, varscan2
- FPR2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs192933693, COSV60672310; called by muse, varscan2
- FSCB | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV61218303; called by muse, mutect2, varscan2
- FTSJ3 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV59562714; called by muse, mutect2, varscan2
- FUT2 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs765205410, COSV67179405; called by muse, mutect2, varscan2
- FYB1 | c.2312A>G p.Y771C (on ENST00000351578 / NM_199335.5; = p.Y817C on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60948079; called by muse, mutect2, varscan2
- FYCO1 | c.4205G>A p.S1402N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV56116523; called by muse, mutect2, varscan2
- FYCO1 | c.2735T>C p.V912A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV99945149; called by muse, mutect2, varscan2
- FYCO1 | c.2008A>G p.I670V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.076); catalogued as rs1484628022; called by mutect2, varscan2
- FZD10 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99969237; called by muse, mutect2
- FZD6 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV62470929; called by muse, mutect2, varscan2
- GABRA4 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.75); PolyPhen probably damaging (1); catalogued as COSV51929035; called by muse, mutect2, varscan2
- GABRA5 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV59480512; called by muse, mutect2, varscan2
- GAL3ST1 | c.1109C>A p.T370N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs1289218966, COSV58892779; called by muse, mutect2, varscan2
- GALNS | c.1548G>T p.K516N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.045); catalogued as COSV51937958; called by muse, mutect2, varscan2
- GALNT12 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV66662831; called by muse, mutect2
- GAREM2 | c.1576T>A p.Y526N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66107551; called by muse, mutect2, varscan2
- GCM2 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV65275773; called by muse, mutect2, varscan2
- GCNT2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65457481; called by muse, mutect2, varscan2
- GDF3 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1440316924, COSV61712284; called by muse, mutect2
- GDI2 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV66334968; called by muse, mutect2, varscan2
- GDPD4 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60019904; called by muse, mutect2
- GEN1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754490164, COSV58056936; called by muse, mutect2, varscan2
- GIPC3 | c.920G>A p.R307H (on ENST00000644946; = p.A303T on NM_133261.3) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as rs769307495, COSV59258213; called by muse, mutect2, varscan2
- GJD4 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV58702650, COSV58702932; called by muse, mutect2
- GLB1L2 | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV60278893; called by muse, mutect2, varscan2
- GLG1 | c.2115+1G>A p.X705_splice | Splice Site (SNP) | VAF 7/121 reads (6%) | catalogued as COSV52668139; called by muse, mutect2
- GLIS3 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60930036; called by muse, mutect2, varscan2
- GOLGA3 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52633131; called by muse, mutect2, varscan2
- GPAT4 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67841033; called by muse, mutect2, varscan2
- GPC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV52785234; called by muse, mutect2, varscan2
- GPC2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV52785243; called by muse, mutect2, varscan2
- GPR158 | c.2031T>A p.D677E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.241); catalogued as COSV66271881; called by muse, mutect2, varscan2
- GPR20 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148158345; called by muse, mutect2, varscan2
- GPR50 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs770934441, COSV54439488; called by muse, mutect2, varscan2
- GPR85 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV51783788; called by muse, mutect2, varscan2
- GRB2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359241313, COSV100353437, COSV57305017; called by muse, mutect2, varscan2
- GREB1L | c.2608A>T p.K870* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV52556925; called by muse, mutect2, varscan2
- GRIA1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53606152; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK5 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.121); catalogued as rs1460677305, COSV53479591; called by muse, mutect2, varscan2
- GRIN2B | c.2359+1G>A p.X787_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | catalogued as COSV74206177; called by muse, mutect2, varscan2
- GRPR | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs867214010, COSV66669572; called by muse, mutect2, varscan2
- GRXCR2 | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV65061279; called by muse, mutect2
- GSE1 | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs777298065, COSV53672644; called by muse, mutect2, varscan2
- GTF2E1 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.059); catalogued as rs1312964560, COSV52204546; called by muse, mutect2, varscan2
- GTF2I | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60401575; called by muse, mutect2, varscan2
- GTF3C2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs911830931, COSV51989511; called by muse, mutect2, varscan2
- GTF3C3 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55832436; called by muse, mutect2, varscan2
- GTPBP3 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763819285, COSV50179674; called by mutect2, varscan2
- GUCY2F | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753973296, COSV54303308; called by mutect2, varscan2
- H2BC18 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58944377; called by muse, mutect2, varscan2
- HAPLN1 | c.310dup p.T104Nfs*8 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | catalogued as rs1561302644; called by mutect2, varscan2
- HARS1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56907158; called by muse, mutect2, varscan2
- HBS1L | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV63201421; called by muse, mutect2, varscan2
- HDAC4 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.793); catalogued as rs771056077, COSV61866789; called by muse, mutect2, varscan2
- HDAC7 | c.1700T>A p.L567H (on ENST00000427332; = p.L606H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV50367383; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as COSV100625709; called by mutect2, varscan2
- HDGFL2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56683113; called by muse, mutect2, varscan2
- HEATR1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV63981539; called by muse, mutect2, varscan2
- HEATR4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs1243365258, COSV58573288; called by muse, mutect2, varscan2
- HEPHL1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs749277008, COSV59891479; called by muse, mutect2, varscan2
- HERC2 | c.10540A>G p.T3514A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55327059; called by muse, mutect2, varscan2
- HERC2 | c.2084A>T p.E695V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV55327082; called by muse, mutect2, varscan2
- HHEX | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.189); catalogued as rs1159967487; called by muse, mutect2, varscan2
- HIF3A | c.526G>A p.G176R (on ENST00000377670 / NM_152795.4; = p.G107R on NM_022462.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368898580; called by muse, mutect2, varscan2
- HIPK1 | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65784911; called by muse, mutect2, varscan2
- HIPK4 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52521494; called by muse, mutect2, varscan2
- HIRA | c.2264G>A p.R755K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.952); catalogued as COSV54275508; called by muse, mutect2, varscan2
- HLA-C | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs72558147, COSV66113635; called by muse, mutect2, varscan2
- HNMT | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV54508117; called by muse, mutect2, varscan2
- HS6ST1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1398695673; called by muse, mutect2
- HSD3B1 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV52490876; called by muse, mutect2
- HSPA1B | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1335368232; called by muse, mutect2, varscan2
- HTT | c.7243G>A p.V2415M | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs759626383, COSV61863173; called by muse, mutect2, varscan2
- HUWE1 | c.4790C>T p.A1597V | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as COSV53348062; called by muse, mutect2, varscan2
- IFT80 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1559937674, COSV100424355; called by muse, mutect2, varscan2
- IFT80 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV58448195; called by muse, mutect2, varscan2
- IGF2BP3 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV99325821; called by muse, mutect2
- IGHD3-9 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 29/142 reads (20%) | catalogued as rs370221435; called by muse, mutect2, varscan2
- IGHMBP2 | c.1369T>C p.Y457H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54822906; called by muse, mutect2, varscan2
- IGKV2D-28 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs751940570, COSV101494551; called by mutect2, varscan2
- IGSF1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs767093474, COSV63836910; called by muse, mutect2, varscan2
- IGSF9B | c.1260dup p.Y421Lfs*60 | Frame Shift Ins (INS) | VAF 26/92 reads (28%) | catalogued as rs775604395; called by mutect2, varscan2
- IKZF1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58786615; called by muse, mutect2, varscan2
- IL3RA | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58431621; called by muse, mutect2
- IL3RA | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs534672301, COSV58431636; called by muse, mutect2
- ILF3 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV51558495; called by muse, mutect2, varscan2
- IMPG1 | c.1244T>A p.V415D | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV64058599; called by muse, mutect2, varscan2
- IP6K3 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.994); catalogued as COSV53390498; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs759821884; called by mutect2, pindel*, varscan2
- IQCN | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV62747805; called by muse, mutect2, varscan2
- IQGAP1 | c.3638C>T p.A1213V | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as rs1460096148, COSV51586402; called by muse, mutect2, varscan2
- IRF9 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60703341; called by muse, mutect2, varscan2
- ISX | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58086873; called by mutect2, varscan2
- ITCH | c.1851G>T p.K617N (on ENST00000262650 / NM_001257137.3; = p.K576N on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as rs778741830; called by muse, mutect2, varscan2
- ITFG2 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57389809; called by muse, mutect2, varscan2
- ITGA10 | c.3160C>T p.Q1054* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV65197652; called by muse, mutect2, varscan2
- ITGA3 | c.226dup p.R76Pfs*27 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs752236693; called by mutect2, pindel, varscan2
- ITGB1 | c.1289T>C p.I430T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV56482522; called by muse, mutect2, varscan2
- ITGB6 | c.2285A>G p.Y762C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777800965, COSV51794905; called by muse, varscan2
- ITIH5 | c.1832G>A p.S611N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53667306; called by muse, mutect2, varscan2
- ITSN1 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs768901601, COSV66082643; called by muse, mutect2, varscan2
- JAK1 | c.3277G>T p.G1093C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53807802; called by muse, mutect2, varscan2
- JAKMIP1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68953239; called by muse, mutect2, varscan2
- JMJD1C | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV67862576; called by muse, mutect2
- JMJD7-PLA2G4B | c.1710-1G>T p.X570_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58022044; called by muse, mutect2, varscan2
- JPH3 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111480296, COSV52468453; called by muse, mutect2, varscan2
- JRK | c.796A>T p.I266F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70629936; called by muse, mutect2, varscan2
- KALRN | c.5044C>T p.R1682W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748367644, COSV62568563; called by mutect2, varscan2
- KALRN | c.5204A>T p.N1735I (on ENST00000360013 / NM_001024660.4; = p.N38I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as COSV52257867; called by muse, varscan2
- KANK1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV63212664; called by muse, mutect2, varscan2
- KCNA6 | c.1304del p.G435Efs*55 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as COSV99768680; called by mutect2, pindel, varscan2
- KCNC1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56394773, COSV56395500; called by muse, mutect2, varscan2
- KCNH2 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV51169240; called by muse, mutect2, varscan2
- KCNJ2 | c.1021T>A p.Y341N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54662141; called by muse, mutect2, varscan2
- KCNJ5 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as rs372447456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK1 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64035285; called by muse, mutect2, varscan2
- KCNMA1 | c.3182G>A p.R1061Q (on ENST00000286628 / NM_001161352.2; = p.R1003Q on NM_002247.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); catalogued as rs764468883, COSV54226083; called by muse, mutect2, varscan2
- KCNV2 | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV66056428; called by mutect2, varscan2
- KCP | c.2739del p.D914Tfs*111 (on ENST00000620378; = p.D974Tfs*111 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs778175457; called by mutect2, pindel, varscan2
- KCTD21 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV60741202; called by muse, mutect2, varscan2
- KCTD3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV52067269; called by muse, mutect2, varscan2
- KDM2A | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV58189904; called by muse, mutect2, varscan2
- KIAA0825 | c.174_177del p.K58Nfs*17 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs747417969; called by pindel, varscan2
- KIAA0895L | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs777071146, COSV51783305; called by muse, mutect2, varscan2
- KIAA0930 | c.95G>A p.W32* (on ENST00000336156 / NM_001009880.2; = p.W37* on NM_015264.2) | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV52663605; called by muse, mutect2, varscan2
- KIF17 | c.2186C>T p.T729I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV56118817; called by muse, mutect2, varscan2
- KIF1B | c.3968C>A p.P1323H (on ENST00000377086 / NM_001365952.1; = p.P1277H on NM_015074.3) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV55809743; called by muse, mutect2, varscan2
- KIFBP | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752833136, COSV62831808; called by muse, mutect2, varscan2
- KIRREL1 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs138458053; called by muse, mutect2, varscan2
- KLHL10 | c.1165T>C p.Y389H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53173412; called by muse, mutect2, varscan2
- KLHL22 | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61021290; called by muse, mutect2, varscan2
- KLHL36 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1465681548; called by muse, mutect2, varscan2
- KLHL6 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.793); catalogued as COSV100384308, COSV100384960; called by muse, mutect2
- KMT2D | c.16052G>T p.R5351L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM138443, COSV56409652, COSV56494348; called by muse, mutect2, varscan2
- KMT2D | c.12205C>G p.L4069V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56425059, COSV56447888, COSV56501485; called by muse, mutect2, varscan2
- KMT2D | c.11608A>G p.M3870V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1249062473, COSV56447917; called by muse, mutect2, varscan2
- KMT2D | c.5060G>A p.R1687H | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56447942, COSV56468442; called by muse, mutect2, varscan2
- KNTC1 | c.4915G>A p.A1639T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1164639248, COSV61080599; called by muse, mutect2, varscan2
- KRT34 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs760710478, COSV67449280; called by muse, mutect2, varscan2
- KRTAP10-7 | c.135dup p.C46Lfs*28 | Frame Shift Ins (INS) | VAF 11/89 reads (12%) | catalogued as rs781883869; called by mutect2, pindel, varscan2
- KRTAP13-1 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV62663493; called by muse, mutect2, varscan2
- KRTAP6-3 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 46/214 reads (21%) | PolyPhen benign (0.025); catalogued as COSV66962986; called by muse, mutect2, varscan2
- LAMA1 | c.3849G>T p.Q1283H | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV104432665, COSV67538310; called by muse, mutect2, varscan2
- LAMA4 | c.3812T>C p.L1271S (on ENST00000230538 / NM_001105206.3; = p.L1264S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57898249; called by muse, mutect2, varscan2
- LAMA5 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756189022, COSV53361493; called by muse, mutect2, varscan2
- LAMP1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs767683537, COSV58148576; called by muse, mutect2, varscan2
- LARS1 | c.246del p.K82Nfs*23 | Frame Shift Del (DEL) | VAF 31/171 reads (18%) | catalogued as COSV50996336; called by mutect2, pindel, varscan2
- LIFR | c.2953G>A p.A985T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as COSV54691477; called by muse, mutect2, varscan2
- LIG3 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV52008159; called by muse, mutect2, varscan2
- LILRB2 | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100078994, COSV58745954; called by muse, mutect2
- LILRB3 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.087); catalogued as COSV99557846; called by muse, mutect2
- LPCAT1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV52038148; called by muse, mutect2, varscan2
- LPCAT4 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59217155; called by muse, mutect2, varscan2
- LRIG3 | c.2656T>C p.S886P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV100292416; called by muse, mutect2, varscan2
- LRP12 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.291); catalogued as COSV52629658; called by muse, mutect2, varscan2
- LRRC14B | c.765del p.T256Pfs*36 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs748566980; called by mutect2, pindel, varscan2
- LRRC36 | c.1963A>T p.M655L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52080120; called by muse, mutect2, varscan2
- LRRC8E | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs752767155, COSV60718297; called by muse, mutect2, varscan2
- LRRK1 | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV52613988; called by muse, mutect2, varscan2
- LRRK2 | c.5255C>A p.S1752Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54155512; called by muse, mutect2, varscan2
- LSP1 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV61134834; called by muse, mutect2, varscan2
- LTBP2 | c.3875G>A p.G1292D | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56209028; called by muse, mutect2, varscan2
- LTBP4 | c.3445G>A p.A1149T (on ENST00000308370 / NM_001042544.1; = p.A1112T on NM_003573.2) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV52582767; called by muse, mutect2, varscan2
- LTK | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as COSV53027938, COSV53028464; called by muse, mutect2, varscan2
- LYST | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV67707767; called by muse, mutect2, varscan2
- MACROH2A2 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV64706802; called by muse, mutect2, varscan2
- MAGEC1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV53581303; called by muse, mutect2
- MAGED2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV54498106; called by mutect2, varscan2
- MAML2 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.086); catalogued as COSV73263680; called by muse, mutect2, varscan2
- MANBA | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs145950049; called by muse, mutect2, varscan2
- MANF | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as rs113724505, COSV99809143; called by muse, mutect2
- MAP2 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs763603161, COSV52281446; called by muse, mutect2, varscan2
- MAP3K10 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1362936194, COSV53422791; called by muse, mutect2, varscan2
- MAP3K2 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs376189453; called by muse, mutect2, varscan2
- MAP3K21 | c.2573A>G p.D858G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1373094855, COSV64041892, COSV64042085; called by muse, mutect2, varscan2
- MAP3K4 | c.2078A>T p.D693V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62334408; called by muse, mutect2
- MAP4 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368502026; called by muse, mutect2, varscan2
- MARCHF4 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56105387, COSV99814403; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs762648935; called by mutect2, pindel
- MCF2L2 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV61054643; called by muse, mutect2, varscan2
- MCM3AP | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52440503; called by muse, mutect2, varscan2
- MCMBP | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as rs1378141859, COSV63509331; called by muse, mutect2, varscan2
- MCTP2 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs376604062, COSV63294092; called by muse, mutect2, varscan2
- MCUB | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV67120018; called by muse, mutect2, varscan2
- MDM1 | c.1148T>C p.V383A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV57446516; called by muse, mutect2, varscan2
- MED10 | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55386196; called by muse, mutect2, varscan2
- MED12 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1222426673, COSV61329412; called by muse, mutect2, varscan2
- MED8 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.853); catalogued as COSV51941261; called by muse, mutect2, varscan2
- MEGF6 | c.4015C>T p.R1339C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs987783133, COSV53890646; called by muse, mutect2, varscan2
- MEIOC | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs982767803, COSV63441809; called by muse, mutect2, varscan2
- MEIS3 | c.1063G>A p.A355T (on ENST00000558555 / NM_001346148.1; = p.A401T on NM_020160.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58983768; called by muse, mutect2, varscan2
- METRNL | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV60760640; called by muse, mutect2, varscan2
- METTL14 | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV66310684; called by muse, mutect2, varscan2
- MFF | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58825019; called by muse, mutect2, varscan2
- MGAM | c.1751A>T p.N584I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV72074775; called by muse, mutect2, varscan2
- MGAT3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs760106779, COSV57864375, COSV57865845; called by muse, mutect2, varscan2
- MIEN1 | c.264+3_264+6del | Splice Region (DEL) | VAF 21/70 reads (30%) | catalogued as rs757438769; called by mutect2, pindel, varscan2
- MIS18BP1 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV60371021; called by muse, mutect2, varscan2
- MLEC | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV57329741; called by muse, mutect2, varscan2
- MMP3 | c.274T>C p.C92R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55406485; called by muse, mutect2, varscan2
- MMP9 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs373663809; called by muse, mutect2, varscan2
- MORC2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV53196949; called by muse, mutect2
- MPHOSPH10 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs570909234, COSV54905478; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs539937334, COSV54915026; called by muse, mutect2
- MPL | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV65245049, COSV65246614; called by muse, mutect2, varscan2
- MPND | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368152281; called by muse, mutect2, varscan2
- MROH7 | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs745862413; called by muse, mutect2, varscan2
- MRPL55 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV54342541; called by muse, mutect2, varscan2
- MRPL58 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as COSV56900940; called by muse, mutect2, varscan2
- MRPL9 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs146264718; called by muse, mutect2
- MRPL9 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV58618306; called by muse, mutect2
- MRTFA | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs202202963; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MTA1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs368709921; called by muse, mutect2
- MTBP | c.1966T>C p.Y656H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59963518; called by muse, mutect2, varscan2
- MTM1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV60335325; called by muse, mutect2, varscan2
- MUC16 | c.43068G>A p.A14356= | Splice Region (SNP) | VAF 57/249 reads (23%) | catalogued as rs1385168957, COSV66692780; called by muse, mutect2, varscan2
- MUC16 | c.37277C>A p.P12426H | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV67470763; called by muse, mutect2, varscan2
- MUC16 | c.21604G>A p.D7202N | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.351); catalogued as rs768515637, COSV67470767; called by muse, mutect2, varscan2
- MUC21 | c.1154G>A p.S385N | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV66221070; called by muse, mutect2, varscan2
- MUC5B | c.13210G>A p.A4404T | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV71592472; called by muse, mutect2, varscan2
- MUTYH | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV58344270; called by muse, mutect2, varscan2
- MUTYH | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV58344273; called by muse, mutect2, varscan2
- MXD3 | c.148del p.Q50Rfs*24 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs866699857; called by mutect2, pindel, varscan2
- MXRA5 | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54237732; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs764857791; called by mutect2, pindel
- MYCBP2 | c.11987C>T p.A3996V (on ENST00000357337; = p.A4034V on NM_015057.5) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62021941; called by muse, mutect2, varscan2
- MYH11 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55555454; called by muse, mutect2, varscan2
- MYH15 | c.5531G>A p.R1844H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs767302033, COSV56311569; called by muse, mutect2, varscan2
- MYH15 | c.934C>T p.L312= | Splice Region (SNP) | VAF 11/68 reads (16%) | catalogued as COSV56311579; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH3 | c.5768C>T p.A1923V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV56865822; called by muse, mutect2, varscan2
- MYO18A | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374765405; called by muse, mutect2, varscan2
- MYO3B | c.3263A>T p.E1088V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV58704998; called by muse, mutect2, varscan2
- MYO5C | c.3553A>G p.K1185E | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55907237; called by muse, mutect2, varscan2
- MYO6 | c.1395T>G p.H465Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.093); catalogued as COSV64119362; called by muse, mutect2, varscan2
- MYOCD | c.812del p.P271Qfs*46 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | catalogued as COSV58512346; called by mutect2, pindel, varscan2
- MYOG | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV54096631; called by muse, mutect2, varscan2
- MYOZ1 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63772731; called by muse, mutect2, varscan2
- MYPOP | c.1109del p.P370Qfs*36 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs746192154; called by mutect2, varscan2
- MZT2A | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | catalogued as rs753638030; called by pindel, varscan2*
- NACC2 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as rs368687607; called by muse, mutect2, varscan2
- NAT2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV54061533; called by muse, mutect2, varscan2
- NAV3 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57084128; called by muse, mutect2, varscan2
- NBEAL2 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs774505879, COSV52758769; called by muse, mutect2, varscan2
- NCBP1 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1315197808, COSV64307667; called by muse, mutect2, varscan2
- NCL | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59546284; called by muse, mutect2
- NCOA6 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as rs369844271; called by muse, mutect2, varscan2
- NDUFAF5 | c.98T>A p.V33D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV52521455; called by muse, mutect2, varscan2
- NEB | c.5978A>T p.Y1993F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51422688; called by muse, mutect2, varscan2
- NEBL | c.1115A>G p.E372G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); catalogued as COSV65803386; called by muse, mutect2, varscan2
- NEK5 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773041763, COSV62878887, COSV62879473; called by muse, mutect2, varscan2
- NEXMIF | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778760434, COSV50022011, COSV50029019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFE2L3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs566561270, COSV50228075; called by muse, mutect2, varscan2
- NGFR | c.66+1del | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs1465683801; called by pindel, varscan2
- NIPAL3 | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99135138; called by muse, mutect2, varscan2
- NIT1 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as rs531981250, COSV63501818; called by muse, mutect2, varscan2
- NLRC5 | c.1346dup p.G450Wfs*105 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRC5 | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV52656511; called by muse, mutect2, varscan2
- NOBOX | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV56194984; called by muse, mutect2, varscan2
- NOC3L | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV64929976; called by muse, mutect2, varscan2
- NOD2 | c.1515del p.S506Pfs*11 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOLC1 | c.1969C>T p.R657* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs747487000; called by muse, mutect2, varscan2
- NOM1 | c.877del p.E293Kfs*34 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | catalogued as rs1181151615; called by mutect2, pindel, varscan2
- NOP56 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61390242; called by muse, mutect2, varscan2
- NPNT | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59754328; called by muse, mutect2, varscan2
- NR0B1 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV66764159; called by muse, mutect2, varscan2
- NR2C1 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV60691261; called by muse, mutect2, varscan2
- NR2F6 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52243933, COSV52243987; called by muse, mutect2, varscan2
- NR3C1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as COSV51541932; called by muse, mutect2, varscan2
- NRAP | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63491099; called by muse, mutect2, varscan2
- NRN1L | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1044247559, COSV59302081; called by muse, varscan2
- NSD2 | c.3842C>A p.P1281H | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56391686; called by muse, mutect2, varscan2
- NSG2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.989); catalogued as COSV57458085; called by muse, mutect2, varscan2
- NT5C1A | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1008659344, COSV52493684; called by muse, mutect2, varscan2
- NUP155 | c.2995C>A p.P999T (on ENST00000231498 / NM_153485.3; = p.P940T on NM_004298.4) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51530549; called by muse, mutect2
- NUP210 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755992121, COSV54407301; called by muse, mutect2, varscan2
- NUP43 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | catalogued as COSV61190100; called by muse, mutect2, varscan2
- NUP98 | c.4625C>T p.A1542V (on ENST00000359171 / NM_001365126.1; = p.A1525V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs569344878, COSV61432809; called by muse, mutect2, varscan2
- NUTM1 | c.1875G>T p.Q625H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59216072; called by muse, mutect2, varscan2
- OAZ1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1411088527; called by muse, mutect2, varscan2
- OBSCN | c.13130A>T p.D4377V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52781361; called by muse, mutect2, varscan2
- OIP5 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1409406920, COSV52971522; called by muse, mutect2, varscan2
- OLFML2B | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs763644969, COSV54196864; called by mutect2, varscan2
- OMA1 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62255684; called by muse, mutect2, varscan2
- OR10A2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1187151677, COSV56299574; called by muse, mutect2
- OR10A7 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs750057831, COSV58278730; called by muse, mutect2, varscan2
- OR10H4 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV59062098; called by muse, mutect2, varscan2
- OR1C1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68715787; called by muse, mutect2, varscan2
- OR1D2 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.811); catalogued as rs971857619, COSV58921753; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 82/339 reads (24%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR51I2 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs549847849, COSV58298932; called by mutect2, varscan2
- OR52E4 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1480177628, COSV57625020; called by muse, mutect2, varscan2
- OR52H1 | c.449T>C p.I150T (on ENST00000322653; = p.I156T on NM_001005289.1) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as COSV59505548; called by muse, mutect2, varscan2
- OR52I2 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760290346, COSV100442827; called by muse, mutect2, varscan2
- OR5H14 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV71194029; called by muse, mutect2, varscan2
- OR5M1 | c.936A>T p.K312N | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV73202043, COSV73202180; called by muse, mutect2, varscan2
- OR5M10 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101595860; called by muse, mutect2, varscan2
- OR8H2 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as COSV57945189; called by muse, mutect2, varscan2
- ORC2 | c.1670_1673del p.L557* | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs754142901; called by pindel, varscan2
- OTUD6B | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs539885905, COSV53443038; called by muse, mutect2, varscan2
- OXNAD1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53267051; called by muse, mutect2, varscan2
- P2RY8 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1179940555, COSV67177312; called by muse, mutect2, varscan2
- PADI2 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs572228579, COSV64953966; called by muse, mutect2, varscan2
- PAN2 | c.2184+1G>A p.X728_splice (on ENST00000425394 / NM_001127460.3; = p.X724_splice on NM_014871.5) | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as COSV57754224; called by muse, mutect2
- PANX2 | c.1760del p.G587Afs*17 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV99348555; called by mutect2, pindel, varscan2
- PARP2 | c.1712A>G p.Y571C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51638021; called by muse, mutect2
- PASK | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV52153865; called by muse, mutect2, varscan2
- PAXBP1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV51609417; called by muse, mutect2, varscan2
- PAXIP1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs928291763, COSV68185974; called by muse, mutect2, varscan2
- PCBP1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs1460640524, COSV57850612; called by muse, mutect2, varscan2
- PCDH11Y | c.598G>A p.V200I (on ENST00000400457 / NM_032973.2; = p.V189I on NM_032971.3) | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as COSV53082324; called by muse, mutect2, varscan2
- PCDHA13 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV56483377; called by muse, mutect2, varscan2
- PCDHB2 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV50578337; called by muse, mutect2, varscan2
- PCDHB4 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52023186; called by muse, mutect2, varscan2
- PCDHGA10 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV53961632; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCIF1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV65026522, COSV65027317; called by muse, mutect2, varscan2
- PCLO | c.6179A>G p.D2060G | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1341121369, COSV61639420; called by muse, mutect2, varscan2
- PCSK1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60734848, COSV60735715; called by muse, mutect2, varscan2
- PCSK5 | c.5330C>T p.A1777V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV70450174; called by muse, mutect2, varscan2
- PCSK7 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV99638920; called by muse, mutect2, varscan2
- PDE12 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV60818698; called by muse, mutect2, varscan2
- PDPR | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55352833, COSV55358427; called by muse, mutect2, varscan2
- PDZD2 | c.5528del p.K1843Rfs*31 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs1184879635; called by mutect2, pindel, varscan2
- PEF1 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs745569188, COSV65483791; called by muse, mutect2, varscan2
- PES1 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58828777; called by muse, mutect2, varscan2
- PFAS | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780319540, COSV58980825; called by muse, mutect2, varscan2
- PGBD5 | c.151G>A p.A51T (on ENST00000525115; = p.A120T on NM_001258311.2) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.296); catalogued as rs767804134, COSV58412051; called by muse, mutect2, varscan2
- PGD | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1433955518, COSV54621707; called by muse, mutect2
- PGLYRP3 | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51950579; called by muse, mutect2
- PHF2 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1357002895; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs761575760; called by mutect2, varscan2
- PHF7 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs370842503; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs748850271; called by pindel, varscan2
- PHIP | c.3783-2A>G p.X1261_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | catalogued as COSV51505282; called by muse, mutect2, varscan2
- PIF1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs753094034, COSV51422406; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs755454854; called by mutect2, pindel, varscan2
- PKLR | c.571T>A p.F191I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV61361404; called by muse, mutect2, varscan2
- PLA2G4D | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV51821218; called by muse, mutect2, varscan2
- PLAG1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV57611836; called by muse, mutect2
- PLCE1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53353123, COSV53355116; called by muse, mutect2, varscan2
- PLCE1 | c.3796G>T p.D1266Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV53353161, COSV53372635; called by muse, mutect2, varscan2
- PLCG1 | c.3823G>A p.E1275K (on ENST00000373271 / NM_182811.2; = p.E1276K on NM_002660.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV54819372; called by muse, mutect2
- PLEC | c.10166C>T p.T3389M (on ENST00000322810 / NM_201380.4; = p.T3279M on NM_000445.5) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs781828296, COSV59643699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.2778G>T p.K926N (on ENST00000322810 / NM_201380.4; = p.K816N on NM_000445.5) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59643740; called by muse, mutect2, varscan2
- PLEKHA2 | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66242795; called by muse, mutect2, varscan2
- PLEKHG4B | c.1361G>A p.R454H (on ENST00000283426; = p.R810H on NM_052909.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.743); catalogued as rs368262746, COSV52048591; called by muse, varscan2
- PLEKHG6 | c.1793_1794insA p.T599Hfs*71 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | catalogued as COSV50601965; called by mutect2, pindel, varscan2
- PLEKHM1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772069486, COSV69598968; called by muse, mutect2, varscan2
- PLXNA4 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58131286; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXNB2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.528); catalogued as rs546928788, COSV63782192; called by muse, mutect2, varscan2
- PNMA8B | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV66535793; called by muse, mutect2
- POGLUT3 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60212900; called by muse, mutect2, varscan2
- POLD1 | c.2007-1G>T p.X669_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV70955430; called by muse, mutect2, varscan2
- POLE | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57681803; called by muse, mutect2, varscan2
- POLR3B | c.2096A>T p.Y699F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV57279729; called by muse, mutect2, varscan2
- POTEC | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 94/491 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV62801152; called by muse, mutect2, varscan2
- PPP1CA | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV57237095; called by muse, mutect2, varscan2
- PPP1R13B | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52452247; called by muse, mutect2, varscan2
- PPP2R3B | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1419224146, COSV66813549; called by muse, mutect2, varscan2
- PPRC1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1228326899, COSV53385853; called by muse, mutect2
- PPT2 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61354541; called by muse, mutect2, varscan2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, mutect2
- PRDM16 | c.3348G>T p.E1116D | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99575470; called by muse, mutect2
- PRDM4 | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200101622, COSV57305999; called by muse, mutect2, varscan2
- PRELID3A | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV61253599; called by muse, mutect2, varscan2
- PRG4 | c.3497G>A p.R1166Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760696470, COSV63355685; called by muse, mutect2, varscan2
- PRICKLE1 | c.2435A>G p.Q812R | Missense Mutation (SNP) | VAF 109/449 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.105); catalogued as COSV58207441; called by muse, mutect2, varscan2
- PRKAB2 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54213400; called by muse, mutect2, varscan2
- PRKD2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV52187229; called by muse, mutect2, varscan2
- PRKDC | c.11144A>G p.Y3715C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58054123; called by muse, mutect2, varscan2
- PRKG1 | c.1839T>A p.N613K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64771451; called by muse, mutect2, varscan2
- PROM1 | c.646T>G p.L216V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.163); catalogued as COSV71699515; called by muse, mutect2
- PRR12 | c.1327G>A p.E443K (on ENST00000615927; = p.E1264K on NM_020719.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101330646, COSV69817882; called by muse, mutect2, varscan2
- PRUNE2 | c.7105C>T p.P2369S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.982); catalogued as COSV65042230; called by muse, mutect2, varscan2
- PSMA6 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs760361768, COSV54837907; called by muse, mutect2, varscan2
- PTBP1 | c.1129G>A p.A377T (on ENST00000349038 / NM_031991.4; = p.A403T on NM_002819.5) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV62458956; called by muse, mutect2, varscan2
- PTBP2 | c.118A>T p.M40L (on ENST00000426398 / NM_001300986.2; = p.M32L on NM_021190.4) | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV64624735; called by muse, mutect2, varscan2
- PTCHD1 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867028011, COSV65060457; called by muse, mutect2, varscan2
- PTCHD3 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs1197371099, COSV71256908; called by muse, mutect2, varscan2
- PTPN11 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV61005958, COSV61009610; called by muse, mutect2, varscan2
- PTPN12 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV50360363; called by muse, mutect2, varscan2
- PTPRB | c.4670G>A p.G1557E | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758187856; called by muse, mutect2
- PTPRF | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302070237, COSV63442464; called by muse, mutect2, varscan2
- PXK | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs779667790, COSV57090508; called by muse, mutect2, varscan2
- QPRT | c.382dup p.A128Gfs*46 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | catalogued as rs757852504; called by mutect2, pindel, varscan2
- R3HCC1L | c.1960G>A p.E654K (on ENST00000612478 / NM_001256619.2; = p.E640K on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54401890, COSV54403407; called by muse, mutect2, varscan2
- R3HDM2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV61289397; called by muse, mutect2, varscan2
- RAB11FIP4 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV57929673; called by muse, mutect2, varscan2
- RAB3GAP1 | c.153T>C p.G51= | Splice Region (SNP) | VAF 55/175 reads (31%) | catalogued as rs1388728601, COSV51480060; called by muse, mutect2, varscan2
- RAB40C | c.811dup p.Q271Pfs*7 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | catalogued as rs1555457247; called by mutect2, varscan2
- RABGAP1L | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52299313; called by muse, mutect2, varscan2
- RABGGTA | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV53770605; called by muse, mutect2, varscan2
- RAD51C | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1567818564, COSV61676374; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RANBP10 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749865571, COSV58158239; called by mutect2, varscan2
- RANBP17 | c.2099T>C p.V700A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs562723609, COSV66651155; called by mutect2, varscan2
- RAPGEF4 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV51392906; called by muse, mutect2, varscan2
- RASA2 | c.1289G>A p.C430Y | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV53940775; called by muse, mutect2, varscan2
- RASGRF1 | c.896del p.L299Yfs*9 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as COSV69181500; called by mutect2, pindel, varscan2
- RASGRP2 | c.1479del p.R494Afs*25 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs774996406; called by mutect2, pindel, varscan2
- RAVER1 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV50329212; called by muse, mutect2
- RBM15 | c.1998C>A p.H666Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.228); catalogued as COSV63923616; called by muse, mutect2, varscan2
- RBM47 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55936051; called by muse, mutect2, varscan2
- RCL1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs745330205, COSV67754133; called by muse, mutect2, varscan2
1,172 further variants in this file (607 protein-altering or splice-affecting, 397 silent, 168 other) are not listed here.
